Somatic mutation profile of tumor specimen TARGET-10-PARTBP-09A (aliquot TARGET-10-PARTBP-09A-01D) from TARGET case TARGET-10-PARTBP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,057 days).
Specimen TARGET-10-PARTBP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f88fcdb-6598-4f8e-9fcf-e6111bf3e870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTBP-10A (Blood Derived Normal), aliquot TARGET-10-PARTBP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d3ee71-1f37-4209-85ab-dc4824b12cb4

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 2, 5'UTR 2, 5'Flank 1, Translation Start Site 1, Nonsense Mutation 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 44/267 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC120 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs375814386, COSV64515756; called by muse, mutect2, varscan2
- CCDC148 | c.1064A>T p.K355M | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); catalogued as COSV51770054; called by muse, mutect2, varscan2
- CNOT3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55368245; called by muse, mutect2, varscan2
- DAB1 | c.1277C>T p.T426M (on ENST00000371231; = p.T393M on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs143039428; called by muse, mutect2, varscan2
- DNAH7 | c.9457G>A p.E3153K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56784664; called by muse, mutect2, varscan2
- NFATC3 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60479294; called by muse, varscan2
- NOTCH1 | c.7183C>T p.Q2395* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV53056886; called by muse, mutect2, varscan2
- PTEN | c.694del p.T232Hfs*24 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | catalogued as COSV64299114, COSV99057991; called by pindel*, varscan2
- SEM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/92 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV50351587; called by muse, mutect2, varscan2
- SOX14 | c.419del p.D140Afs*85 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as COSV60163410; called by mutect2, pindel, varscan2
- ZFP2 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV63726934, COSV63727065; called by muse, mutect2, varscan2
- USH2A | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2
- LEXM | c.672T>C p.Y224= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as rs1393495643; called by muse, mutect2, varscan2
- NOTCH1 | c.7182G>A p.Q2394= | Silent (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1338C>T p.N446= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as COSV54040582; called by muse, mutect2, varscan2
- RDH8 | c.808C>A p.R270= (on ENST00000651512; = p.R250= on NM_015725.4) | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1249737 A>T | 5'Flank (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- LMO1 | c.-172G>A | 5'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- MKRN3 | c.*124C>A | 3'UTR (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- OBP2B | c.-42C>T | 5'UTR (SNP) | VAF 8/16 reads (50%) | catalogued as rs1461249587; called by mutect2, varscan2
- PRR12 | c.51+429G>A | Intron (SNP) | VAF 18/35 reads (51%) | catalogued as rs761955652, COSV55871657; called by muse, mutect2, varscan2
